Somatic mutation profile of tumor specimen ALCH-B065-TTP1-A (aliquot ALCH-B065-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B065, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.3 years (26,401 days).
Specimen ALCH-B065-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd2825ea-9ad1-4ef3-8fde-e3696d0f2ba5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B065-NB1-A (Blood Derived Normal), aliquot ALCH-B065-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a92b5249-b71c-4031-8cb2-d429d59c81f5

The open-access MAF lists 47 somatic variants for this specimen: 34 protein-altering or splice-affecting, 6 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 6, Intron 3, Nonsense Mutation 3, 5'UTR 2, 5'Flank 1, In Frame Del 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 64/447 reads (14%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel
- FUS | c.1013C>T p.T338M | Missense Mutation (SNP) | VAF 19/551 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54217250; called by muse, mutect2
- HRNR | c.5696A>G p.Q1899R | Missense Mutation (SNP) | VAF 186/3324 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.17); catalogued as rs1316907196; called by muse, mutect2
- LRRC2 | c.1046T>C p.I349T | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as rs769382026; called by muse, mutect2, varscan2
- MROH1 | c.1487G>A p.R496H | Missense Mutation (SNP) | VAF 53/900 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.395); catalogued as rs1433381128; called by muse, mutect2
- OR2T1 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as rs140525966; called by muse, mutect2
- OR4Q3 | c.840C>G p.F280L | Missense Mutation (SNP) | VAF 32/654 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.018); catalogued as COSV100057211; called by muse, mutect2
- SLC45A1 | c.1571G>A p.R524H | Missense Mutation (SNP) | VAF 10/181 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs963869397; called by muse, mutect2
- SNED1 | c.2587C>T p.H863Y | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as COSV100123449; called by muse, mutect2, varscan2
- SSR1 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 45/296 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); catalogued as rs747697031; called by muse, mutect2, varscan2
- TAAR9 | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV71512180; called by muse, mutect2
- UGT1A7 | c.773T>G p.V258G | Missense Mutation (SNP) | VAF 59/271 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV60848169; called by muse, mutect2, varscan2
- ZNF107 | c.1781A>C p.N594T | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0.035); catalogued as COSV61332523; called by muse, mutect2
- ZNF385D | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 21/332 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as rs770545519, COSV55753651, COSV55768121; called by muse, mutect2
- AC009053.1 | n.816G>T | Splice Region (SNP) | VAF 10/111 reads (9%) | called by muse, mutect2
- BCORL1 | c.2828A>G p.D943G | Missense Mutation (SNP) | VAF 47/260 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- BORA | c.1066G>A p.E356K (on ENST00000613797; = p.E281K on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/205 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- C3 | c.4760C>T p.P1587L | Missense Mutation (SNP) | VAF 189/807 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- CYP2B6 | c.139G>T p.D47Y | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- DMD | c.8302G>T p.G2768C | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); called by muse, mutect2
- DYRK4 | c.482A>G p.D161G | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); called by muse, mutect2
- FPR3 | c.491G>A p.W164* | Nonsense Mutation (SNP) | VAF 15/164 reads (9%) | called by muse, mutect2, varscan2
- KIAA1328 | c.786A>G p.I262M | Missense Mutation (SNP) | VAF 16/285 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2
- PRELID1 | c.393G>C p.W131C | Missense Mutation (SNP) | VAF 18/398 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- PRG4 | c.3069G>C p.K1023N | Missense Mutation (SNP) | VAF 36/778 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.065); called by muse, mutect2
- PRPF8 | c.233A>G p.N78S | Missense Mutation (SNP) | VAF 98/520 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SEPTIN1 | c.760G>A p.D254N (on ENST00000321367; = p.D207N on NM_052838.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2
- SPTA1 | c.4143G>T p.E1381D | Missense Mutation (SNP) | VAF 77/598 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- TBCB | c.415G>T p.A139S | Missense Mutation (SNP) | VAF 58/444 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- THOC3 | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 64/661 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); called by muse, mutect2
- USP7 | c.1739G>T p.G580V | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); called by muse, mutect2
- ZNF461 | c.49C>T p.Q17* | Nonsense Mutation (SNP) | VAF 24/625 reads (4%) | called by muse, mutect2
- ZNF630 | c.1159A>T p.M387L | Missense Mutation (SNP) | VAF 14/318 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- ZNF729 | c.3744T>A p.C1248* | Nonsense Mutation (SNP) | VAF 23/212 reads (11%) | called by muse, mutect2, varscan2
- ACTL9 | c.699G>A p.A233= | Silent (SNP) | VAF 18/184 reads (10%) | catalogued as rs1258677707, COSV61007181; called by muse, mutect2
- HLA-C | c.492T>A p.A164= | Silent (SNP) | VAF 91/934 reads (10%) | called by muse, mutect2
- MAP3K15 | c.2307C>A p.I769= | Silent (SNP) | VAF 19/113 reads (17%) | catalogued as rs757714655, COSV58837127; called by muse, mutect2, varscan2
- OR8B4 | c.786T>A p.S262= | Silent (SNP) | VAF 10/274 reads (4%) | called by muse, mutect2
- PSG1 | c.375A>T p.I125= | Silent (SNP) | VAF 43/105 reads (41%) | catalogued as rs1383506790; called by muse, mutect2, varscan2
- RBMXL3 | c.3150C>T p.G1050= | Silent (SNP) | VAF 40/503 reads (8%) | catalogued as rs1224573894; called by muse, mutect2
- CCS | c.-75T>G | 5'UTR (SNP) | VAF 8/164 reads (5%) | called by muse, mutect2
- CYP19A1 | c.-30A>T | 5'UTR (SNP) | VAF 12/317 reads (4%) | called by muse, mutect2
- EPN1 | c.-101-1355A>G | Intron (SNP) | VAF 34/181 reads (19%) | called by muse, mutect2, varscan2
- GFOD1 | c.253+16358A>T | Intron (SNP) | VAF 5/28 reads (18%) | catalogued as rs1262184449; called by muse, varscan2
- LGR6 | chr1:202188990 C>T | 5'Flank (SNP) | VAF 12/150 reads (8%) | called by muse, mutect2
- MAZ | c.*236A>T | 3'UTR (SNP) | VAF 78/326 reads (24%) | called by muse, mutect2, varscan2
- TOX4 | c.6+44G>A | Intron (SNP) | VAF 28/399 reads (7%) | called by muse, mutect2
